Somatic mutation profile of tumor specimen TCGA-CN-4727-01A (aliquot TCGA-CN-4727-01A-01D-1434-08) from TCGA case TCGA-CN-4727, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.8 years (20,748 days).
Specimen TCGA-CN-4727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00fcf521-81d0-4d82-937f-5f5c627aaaa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4727-10A (Blood Derived Normal), aliquot TCGA-CN-4727-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b593ce-bf26-4dd6-808a-722719b08a60

The open-access MAF lists 471 somatic variants for this specimen: 357 protein-altering or splice-affecting, 101 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 298, Silent 101, Nonsense Mutation 24, Frame Shift Del 17, Splice Site 13, RNA 5, Intron 4, 3'UTR 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 102/169 reads (60%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9973C>T p.P3325S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as rs1271512259, COSV101447062; called by muse, mutect2, varscan2
- ABCB6 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as CM120215, COSV99522036; called by muse, varscan2
- ABCC11 | c.2150G>A p.S717N | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62323397; called by muse, mutect2, varscan2
- ACADS | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.274); catalogued as COSV99656764; called by muse, mutect2, varscan2
- ACSS3 | c.1356G>T p.E452D | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs747017715, COSV54095575, COSV99699185; called by muse, mutect2, varscan2
- ACTC1 | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as CM081513, COSV51759371, COSV99292022; called by muse, mutect2, varscan2
- ADCY2 | c.1841T>A p.I614N | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.134); catalogued as COSV100603409; called by muse, mutect2, varscan2
- ADGRB3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV101001042, COSV101001229; called by muse, mutect2, varscan2
- ADGRB3 | c.896A>C p.Q299P | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.966); catalogued as COSV101001230; called by muse, mutect2, varscan2
- ADGRL1 | c.2509C>T p.H837Y (on ENST00000340736 / NM_001008701.3; = p.H832Y on NM_014921.5) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100529663; called by muse, mutect2, varscan2
- ADGRV1 | c.12551T>C p.L4184S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101316214; called by muse, mutect2, varscan2
- AFF1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100320868; called by muse, mutect2, varscan2
- AFF3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100419595; called by muse, mutect2, varscan2
- AHI1 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs762906949, COSV99663235; called by muse, mutect2, varscan2
- AHNAK2 | c.13508A>G p.Q4503R | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs777576226, COSV100318272; called by muse, mutect2, varscan2
- AMPH | c.1763A>T p.Q588L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100342940; called by muse, mutect2, varscan2
- ANK2 | c.2782A>G p.I928V | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.578); catalogued as COSV100002877; called by muse, mutect2, varscan2
- ANKRD27 | c.1424A>C p.Q475P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100042989; called by muse, mutect2, varscan2
- AP3B2 | c.2040C>A p.D680E | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.421); catalogued as COSV99916749; called by muse, mutect2
- APC2 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV99279656; called by muse, mutect2, varscan2
- ART1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs771137157, COSV99167211; called by muse, mutect2, varscan2
- ASAH2 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.513); catalogued as rs767544067; called by muse, mutect2, varscan2
- ASB13 | c.376A>C p.M126L | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV100731386; called by muse, mutect2, varscan2
- ASB5 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1561252325, COSV99641913; called by muse, mutect2, varscan2
- ATP12A | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 259/713 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs1340424763, COSV99518054; called by muse, mutect2, varscan2
- ATP6V1H | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100778719, COSV62218481; called by muse, mutect2
- ATP8A2 | c.2890C>T p.H964Y | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV54938053, COSV99683033; called by muse, mutect2, varscan2
- ATRNL1 | c.3808G>T p.E1270* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100371873; called by muse, mutect2
- AVPR1A | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs569407663, COSV100146880; called by muse, mutect2, varscan2
- BET1 | c.20-1G>T p.X7_splice | Splice Site (SNP) | VAF 37/113 reads (33%) | catalogued as COSV99747328; called by muse, mutect2, varscan2
- BICRA | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101194400; called by muse, mutect2, varscan2
- BRINP1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1350604797, COSV56297229, COSV99776482; called by muse, mutect2, varscan2
- BTBD11 | c.3135T>A p.Y1045* (on ENST00000280758 / NM_001018072.2; = p.Y582* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV99776411; called by muse, mutect2, varscan2
- BTN3A3 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99764959; called by muse, mutect2, varscan2
- C1orf87 | c.1422G>C p.W474C | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967183; called by muse, mutect2, varscan2
- C3 | c.2128C>G p.R710G | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55568761, COSV99836976; called by muse, mutect2, varscan2
- C6orf120 | c.180C>A p.N60K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV100179195; called by muse, mutect2, varscan2
- C7 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100496216, COSV100496495; called by muse, mutect2, varscan2
- CA10 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs766820678, COSV53360349; called by muse, mutect2, varscan2
- CACNA1E | c.4372C>T p.R1458C | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs774399787, COSV62435602; called by muse, mutect2, varscan2
- CACNA1S | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.178); catalogued as rs772789447, COSV100755187; called by muse, mutect2, varscan2
- CADM2 | c.1093C>G p.P365A (on ENST00000407528 / NM_001167674.2; = p.P367A on NM_153184.4) | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV101057709, COSV67373757; called by muse, mutect2, varscan2
- CAMK2B | c.1858A>T p.I620F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99323268; called by muse, mutect2, varscan2
- CCDC171 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV99901327; called by muse, mutect2, varscan2
- CCDC88C | c.3841G>A p.E1281K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV101105949; called by muse, varscan2
- CCT5 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs11557654; called by muse, mutect2, varscan2
- CDH12 | c.1724G>C p.S575T | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV101202956; called by muse, mutect2, varscan2
- CDH20 | c.1934A>C p.H645P | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99405940; called by muse, mutect2, varscan2
- CEL | c.2194G>T p.G732C (on ENST00000673714; = p.G729C on NM_001807.6) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100672637; called by muse, mutect2, varscan2
- CELSR3 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51162690; called by muse, mutect2, varscan2
- CEMIP2 | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV100987443; called by muse, mutect2, varscan2
- CEMP1 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747949867, COSV99566007; called by muse, mutect2, varscan2
- CEP128 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99825373; called by muse, mutect2, varscan2
- CHD4 | c.4542C>G p.N1514K (on ENST00000357008 / NM_001363606.2; = p.N1527K on NM_001273.5) | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.164); catalogued as COSV100538511; called by muse, mutect2, varscan2
- CLK2 | c.748A>T p.T250S (on ENST00000368361 / NM_001294339.2; = p.T249S on NM_003993.4) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV100226821; called by muse, mutect2, varscan2
- CLVS1 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV100370313; called by muse, mutect2, varscan2
- CNTN6 | c.557T>A p.V186E | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100611322; called by muse, mutect2, varscan2
- COL11A1 | c.3763G>T p.G1255C | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617485; called by muse, mutect2, varscan2
- COL11A1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs376421641; called by muse, mutect2, varscan2
- COL22A1 | c.1043G>T p.R348M | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100279429; called by muse, mutect2, varscan2
- COL28A1 | c.3142A>C p.T1048P | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101258799; called by muse, mutect2, varscan2
- CPAMD8 | c.3026A>G p.Q1009R (on ENST00000651564; = p.Q962R on NM_015692.5) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV101488543; called by muse, varscan2
- CPLX1 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as rs551494928, COSV100408356; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 44/134 reads (33%) | catalogued as rs1562753933; called by mutect2, varscan2
- CSF3R | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.138); catalogued as COSV100118020, COSV58965874; called by muse, mutect2, varscan2
- CSMD3 | c.3884A>T p.K1295M (on ENST00000297405 / NM_001363185.1; = p.K1191M on NM_052900.3) | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52283532; called by muse, mutect2, varscan2
- CUBN | c.4238C>A p.P1413Q | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.328); catalogued as COSV100913100; called by muse, mutect2, varscan2
- CXCR4 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99603242; called by muse, mutect2, varscan2
- CYP2C18 | c.1432C>A p.R478S | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs577595661, COSV99608742; called by muse, mutect2, varscan2
- DAB1 | c.714A>T p.Q238H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100140444; called by muse, mutect2, varscan2
- DCAF5 | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV100432149, COSV100432660, COSV58458996; called by muse, mutect2, varscan2
- DCDC1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1261620007, COSV100663854; called by muse, mutect2, varscan2
- DCHS1 | c.925G>C p.A309P | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV100202303, COSV55034407; called by muse, varscan2
- DDX53 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100029008; called by muse, mutect2, varscan2
- DDX60 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101190547; called by muse, mutect2, varscan2
- DGKI | c.2162C>G p.P721R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99935945; called by muse, mutect2, varscan2
- DIP2C | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 166/357 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99792771; called by muse, mutect2, varscan2
- DNAH5 | c.12060G>T p.M4020I | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV99451823; called by muse, mutect2, varscan2
- DNMBP | c.2703-2A>G p.X901_splice | Splice Site (SNP) | VAF 45/176 reads (26%) | catalogued as COSV100144114; called by muse, mutect2, varscan2
- DPP6 | c.862C>T p.L288F (on ENST00000377770 / NM_001364500.2; = p.L226F on NM_001936.5) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100126792; called by muse, mutect2, varscan2
- DRD3 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.107); catalogued as rs768748323, COSV99879556, COSV99879648; called by muse, mutect2, varscan2
- DSCAM | c.3073del p.R1025Efs*30 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as COSV68037108; called by mutect2, pindel, varscan2
- DSEL | c.632G>C p.W211S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as COSV100025880; called by muse, mutect2, varscan2
- DST | c.3253C>T p.R1085W (on ENST00000361203 / NM_001374722.1; = p.R759W on NM_001723.6) | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs200853096, COSV99758209; called by muse, mutect2, varscan2
- DYSF | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs764849844, COSV50308878; called by muse, mutect2, varscan2
- EDNRB | c.1243G>A p.V415I (on ENST00000377211 / NM_001201397.1; = p.V325I on NM_000115.5) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs201437745, COSV57519503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB13 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV100516757; called by muse, mutect2, varscan2
- ERBB4 | c.2080-1G>T p.X694_splice | Splice Site (SNP) | VAF 53/97 reads (55%) | catalogued as COSV99038402, COSV99628344; called by muse, mutect2, varscan2
- ETFA | c.40-1G>T p.X14_splice | Splice Site (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99144257; called by muse, mutect2, varscan2
- EYA4 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1190456495, COSV100766080; called by muse, mutect2, varscan2
- FAH | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs754844306, COSV99930410; called by muse, mutect2, varscan2
- FAM135B | c.3521T>C p.L1174P | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425727; called by muse, mutect2, varscan2
- FAM155A | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101029247; called by muse, mutect2, varscan2
- FAM227B | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV100175342; called by muse, mutect2, varscan2
- FAT3 | c.4159C>A p.Q1387K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV99968056; called by muse, mutect2, varscan2
- FMN1 | c.2858C>A p.P953H (on ENST00000616417 / NM_001277313.2; = p.P730H on NM_001103184.4) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100569073; called by muse, mutect2, varscan2
- FPR2 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as COSV100389348; called by muse, mutect2, varscan2
- FRMPD3 | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99346016; called by muse, mutect2, varscan2
- FSTL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820847; called by muse, mutect2, varscan2
- GAB4 | c.687-1G>C p.X229_splice | Splice Site (SNP) | VAF 27/117 reads (23%) | catalogued as rs1429053796, COSV101272038; called by muse, mutect2, varscan2
- GCK | c.1297A>T p.S433C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as CX091670, COSV99790059; called by muse, mutect2, varscan2
- GREB1 | c.3773T>C p.I1258T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV99303345; called by muse, mutect2, varscan2
- GSPT2 | c.1632C>A p.H544Q | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468251; called by muse, mutect2, varscan2
- GTF2F1 | c.323G>T p.R108M | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV101081315; called by muse, varscan2
- H3C2 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV99451445, COSV99451609; called by muse, mutect2
- HDAC9 | c.2800G>T p.G934C | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs78483718, COSV101286873; called by muse, mutect2, varscan2
- HELZ | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1479308983, COSV100698905; called by muse, mutect2, varscan2
- HHIPL2 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs774399749, COSV100596981; called by muse, mutect2, varscan2
- HIP1 | c.2604G>A p.W868* | Nonsense Mutation (SNP) | VAF 81/328 reads (25%) | catalogued as COSV100417857; called by muse, mutect2, varscan2
- HSPA13 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99580171; called by muse, mutect2, varscan2
- ICE1 | c.3831C>A p.C1277* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99665192; called by muse, mutect2
- IFI44L | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100655037; called by muse, mutect2, varscan2
- IGF2R | c.6538A>G p.I2180V | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as COSV100807784; called by muse, mutect2, varscan2
- IL12B | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99180361; called by muse, mutect2, varscan2
- IL12RB2 | c.2302A>G p.K768E | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99255417; called by muse, mutect2, varscan2
- IL1RAPL1 | c.987G>T p.L329F | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100148569; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100781638; called by muse, mutect2, varscan2
- IL9R | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as COSV54899057, COSV99730017; called by muse, mutect2
- INPPL1 | c.1443G>A p.W481* | Nonsense Mutation (SNP) | VAF 175/461 reads (38%) | catalogued as COSV99996434; called by mutect2, varscan2
- IQCN | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375802609; called by muse, mutect2, varscan2
- JMJD1C | c.3485A>T p.K1162M | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550714; called by muse, mutect2, varscan2
- KATNAL1 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV101017067; called by muse, mutect2, varscan2
- KEAP1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50263607, COSV50635893; called by muse, mutect2, varscan2
- KHDC3L | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1488094962, COSV64863982, COSV99059405; called by muse, mutect2, varscan2
- KIAA0586 | c.944G>A p.S315N (on ENST00000619416 / NM_001244190.2; = p.S330N on NM_014749.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99708513; called by muse, mutect2, varscan2
- KLF8 | c.897A>T p.T299= | Splice Region (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100808322; called by muse, mutect2, varscan2
- KRTAP21-1 | c.213C>A p.C71* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | catalogued as COSV100624946; called by muse, mutect2
- KSR1 | c.2077C>A p.Q693K (on ENST00000644974 / NM_001367810.1; = p.Q578K on NM_014238.2) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99260145; called by muse, mutect2, varscan2
- LAMA1 | c.8063G>T p.S2688I | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101057013; called by muse, mutect2, varscan2
- LAMA1 | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 118/506 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV101057015; called by muse, mutect2, varscan2
- LAMA4 | c.2275C>A p.L759I (on ENST00000230538 / NM_001105206.3; = p.L752I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100037389, COSV57902171; called by muse, mutect2, varscan2
- LCA5 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1448393195, COSV100878335; called by muse, mutect2, varscan2
- LIMS2 | c.167A>C p.Y56S (on ENST00000355119 / NM_001161403.3; = p.Y80S on NM_017980.4) | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55753959, COSV99760696; called by muse, mutect2, varscan2
- LONP2 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99589393; called by muse, mutect2
- LRIT2 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV100928336; called by muse, mutect2, varscan2
- LRP2 | c.6618G>T p.W2206C | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789476; called by muse, mutect2, varscan2
- LRRC23 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs1220666573, COSV50387104; called by muse, mutect2, varscan2
- LRRC37A3 | c.4357G>T p.D1453Y | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100141029, COSV100141274; called by muse, mutect2, varscan2
- LRRTM4 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101298995; called by muse, mutect2, varscan2
- LTBP1 | c.1275C>A p.F425L (on ENST00000404816 / NM_206943.4; = p.F99L on NM_000627.4) | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100617678; called by muse, mutect2, varscan2
- LTBP1 | c.3256G>T p.G1086W (on ENST00000404816 / NM_206943.4; = p.G760W on NM_000627.4) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99698526; called by muse, mutect2, varscan2
- LVRN | c.374T>C p.L125S | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as rs1300208302, COSV63497785; called by muse, mutect2, varscan2
- M1AP | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99284140; called by muse, mutect2, varscan2
- MAB21L1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100080712, COSV100082276; called by muse, mutect2, varscan2
- MACC1 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100256038; called by muse, mutect2, varscan2
- MAEL | c.843A>T p.T281= | Splice Region (SNP) | VAF 52/156 reads (33%) | catalogued as COSV100774762; called by muse, mutect2, varscan2
- MAEL | c.1041+1G>T p.X347_splice | Splice Site (SNP) | VAF 48/158 reads (30%) | catalogued as COSV100901901; called by muse, mutect2, varscan2
- MAGEB18 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99082041; called by muse, mutect2, varscan2
- MCRS1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV99235508; called by muse, mutect2, varscan2
- MDN1 | c.2150A>C p.K717T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101021567; called by muse, mutect2, varscan2
- MED12L | c.2019G>T p.L673F | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.452); catalogued as COSV99853920; called by muse, mutect2, varscan2
- MEF2C | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100425762; called by muse, mutect2, varscan2
- MEP1A | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs765090084, COSV57919378, COSV57921600; called by muse, mutect2, varscan2
- MGRN1 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99274517; called by muse, mutect2, varscan2
- MKI67 | c.8690A>T p.D2897V | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV100896810; called by muse, mutect2, varscan2
- MOV10L1 | c.790T>G p.L264V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV99434423; called by muse, mutect2, varscan2
- MSH3 | c.3131-1G>T p.X1044_splice | Splice Site (SNP) | VAF 43/185 reads (23%) | catalogued as COSV99434665; called by muse, mutect2, varscan2
- MUC5B | c.10007C>T p.T3336I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV101500551; called by muse, mutect2, varscan2
- MUC5B | c.12655C>A p.R4219S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101500552; called by muse, mutect2, varscan2
- MUC5B | c.13496C>A p.S4499Y | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV101500553, COSV71594333; called by muse, mutect2, varscan2
- MYH13 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369838383, COSV99352643; called by muse, mutect2, varscan2
- MYH3 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs765604070, COSV99878528; called by muse, mutect2, varscan2
- MYOT | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.353); catalogued as COSV99525037; called by muse, mutect2, varscan2
- MYT1L | c.1880C>G p.T627R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NALCN | c.1760C>A p.T587N | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99216460; called by muse, mutect2, varscan2
- NAV3 | c.2513G>C p.S838T | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99893336; called by muse, mutect2, varscan2
- NBEA | c.3268G>C p.V1090L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.785); catalogued as COSV100082272; called by muse, mutect2, varscan2
- NCF4 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50627679, COSV50630011; called by muse, mutect2, varscan2
- NEK5 | c.1698T>A p.S566R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100839270; called by muse, mutect2, varscan2
- NFASC | c.319G>T p.G107W (on ENST00000339876 / NM_001378329.1; = p.G101W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100364820, COSV58366690; called by muse, mutect2, varscan2
- NFKBIZ | c.1135A>T p.S379C | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as COSV100397138; called by muse, mutect2, varscan2
- NID1 | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV99937871; called by muse, mutect2, varscan2
- NISCH | c.4354G>A p.G1452R | Missense Mutation (SNP) | VAF 185/362 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100401985; called by muse, varscan2
- NLRP8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs764375811, COSV52585164; called by muse, mutect2, varscan2
- NOTCH2 | c.5394C>G p.D1798E | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99865479; called by muse, mutect2, varscan2
- NOX3 | c.1205G>A p.C402Y | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV99343430; called by muse, mutect2, varscan2
- NPAP1 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs749705329, COSV100275709; called by muse, mutect2, varscan2
- NPFFR2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1310608783, COSV100441002; called by muse, mutect2, varscan2
- NPFFR2 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.288); catalogued as COSV100441004; called by muse, mutect2, varscan2
- NPHS1 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62289861; called by muse, mutect2, varscan2
- NR0B1 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as CM980036, COSV66764939; called by muse, mutect2, varscan2
- NR4A2 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as COSV100277290; called by muse, mutect2, varscan2
- NRSN2 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101206804; called by muse, mutect2, varscan2
- NSD1 | c.2875G>T p.G959* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100729615; called by muse, mutect2, varscan2
- NSD1 | c.5782G>T p.G1928* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100729616, COSV61785493; called by muse, mutect2, varscan2
- NUP58 | c.1138A>G p.I380V | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as rs764411980, COSV101098805; called by muse, mutect2, varscan2
- OR10Q1 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57470988; called by muse, mutect2, varscan2
- OR14I1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1272040059, COSV61201233; called by muse, mutect2, varscan2
- OR14J1 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV101012817; called by muse, mutect2, varscan2
- OR2AG2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100643137; called by muse, mutect2, varscan2
- OR2T4 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV100822545; called by muse, mutect2, varscan2
- OR4K2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 192/734 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs867712370, COSV53851610; called by muse, mutect2, varscan2
- OR4M1 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 216/848 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100271348; called by muse, varscan2
- OR5I1 | c.335C>A p.T112K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100041573; called by muse, mutect2, varscan2
- OR5J2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV56620910, COSV56621159; called by muse, mutect2, varscan2
- OR5M3 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.944); catalogued as COSV100392594; called by muse, mutect2, varscan2
- OR5T1 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.765); catalogued as COSV100479143, COSV57303259; called by muse, mutect2, varscan2
- OR6F1 | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV100129402, COSV57469581; called by mutect2, varscan2
- OR6N1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625235, COSV100625267; called by muse, mutect2, varscan2
- OR7A5 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV100457852; called by muse, mutect2, varscan2
- OR8G5 | c.340A>C p.M114L | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV100422262, COSV100422549, COSV58380413; called by muse, mutect2, varscan2
- OTOGL | c.5429A>G p.K1810R (on ENST00000547103; = p.K1801R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as rs755871184, COSV100087546; called by muse, mutect2, varscan2
- PAK5 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 137/340 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100781543; called by muse, mutect2, varscan2
- PAPPA2 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV100866878; called by muse, mutect2, varscan2
- PCDHA5 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV100972439, COSV65357845; called by muse, mutect2, varscan2
- PCDHAC1 | c.2881A>T p.S961C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99151247; called by muse, mutect2, varscan2
- PCDHB6 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99170489; called by muse, mutect2, varscan2
- PCDHGA1 | c.1371C>A p.Y457* | Nonsense Mutation (SNP) | VAF 39/151 reads (26%) | catalogued as COSV100966021; called by muse, mutect2, varscan2
- PCDHGB4 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769160604, COSV99542393; called by muse, mutect2, varscan2
- PCGF3 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100745371; called by muse, mutect2, varscan2
- PDE10A | c.2194G>C p.A732P | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV100605347; called by muse, mutect2, varscan2
- PDE3A | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762507; called by muse, mutect2, varscan2
- PDS5B | c.3875G>T p.R1292L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100221232, COSV59724752; called by muse, mutect2, varscan2
- PEG3 | c.2665C>A p.R889S | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55634973, COSV99688124; called by muse, mutect2, varscan2
- PGM5 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs879986279; called by muse, mutect2, varscan2
- PHC2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs201647557, COSV99931215; called by muse, mutect2, varscan2
- PI4K2B | c.624+1G>A p.X208_splice | Splice Site (SNP) | VAF 32/147 reads (22%) | catalogued as COSV99335578; called by muse, mutect2, varscan2
- PIP4P1 | c.387T>A p.C129* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99164497; called by muse, mutect2
- PITPNM2 | c.452A>T p.N151I | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99759313; called by muse, mutect2, varscan2
- PKD1L1 | c.6471C>G p.Y2157* | Nonsense Mutation (SNP) | VAF 63/153 reads (41%) | catalogued as COSV99220676; called by muse, mutect2, varscan2
- PKHD1 | c.7618C>G p.L2540V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV100583815, COSV100584816; called by muse, mutect2, varscan2
- PKHD1L1 | c.3514C>G p.L1172V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1308270894, COSV101006578; called by muse, mutect2, varscan2
- PKP3 | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV100230165; called by muse, mutect2, varscan2
- PLEKHG2 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV99217807; called by muse, mutect2, varscan2
- PLEKHO1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99215310; called by muse, mutect2, varscan2
- PNMA3 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs1569523354, COSV100937637; called by muse, mutect2, varscan2
- POLQ | c.6296G>T p.C2099F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as COSV99952560; called by muse, mutect2, varscan2
- PPFIA4 | c.1520C>A p.S507Y (on ENST00000447715; = p.S482Y on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV99690757; called by muse, mutect2
- PPIP5K2 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383824, COSV100384014; called by muse, varscan2
- PPP1R3A | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV99493501; called by muse, mutect2, varscan2
- PRDM9 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99690767; called by muse, mutect2, varscan2
- PRDM9 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.216); catalogued as rs1267472661, COSV57004186; called by muse, mutect2, varscan2
- PRKD1 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121091; called by muse, mutect2, varscan2
- PRKDC | c.3728A>T p.Y1243F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100041648; called by muse, mutect2, varscan2
- PRLR | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1419095074, COSV99184570; called by muse, mutect2, varscan2
- PROS1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101260675; called by muse, mutect2, varscan2
- PROX1 | c.1467G>A p.M489I | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs761424919, COSV99799851; called by muse, mutect2, varscan2
- PRUNE2 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100944868; called by muse, mutect2, varscan2
- PSG1 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 71/429 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV99740818; called by muse, mutect2, varscan2
- PSG8 | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 211/866 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs773480083, COSV100126467; called by muse, mutect2, varscan2
- PSMC5 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99856535; called by muse, mutect2, varscan2
- PTER | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100126757; called by muse, mutect2, varscan2
- PTH | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.675); catalogued as rs1476002397, COSV99961708; called by muse, mutect2, varscan2
- PTH1R | c.1473C>A p.S491R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100481076; called by muse, mutect2, varscan2
- PTPN12 | c.1231A>C p.K411Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV99950534; called by muse, mutect2, varscan2
- PTPN14 | c.2665A>T p.T889S | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100872804; called by muse, mutect2
- RAB32 | c.135C>G p.Y45* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100832410, COSV62249277; called by muse, mutect2, varscan2
- RASGEF1B | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100021041; called by muse, mutect2, varscan2
- RECQL4 | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as COSV52882965, COSV99467959; called by muse, varscan2
- REG1A | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1377518172, COSV99286865; called by muse, mutect2, varscan2
- RGR | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs372173241, COSV100812948; called by muse, mutect2
- RHOU | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100797178; called by muse, mutect2, varscan2
- ROBO2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100168358, COSV100170181; called by muse, mutect2, varscan2
- RP1L1 | c.6280G>A p.A2094T | Missense Mutation (SNP) | VAF 188/385 reads (49%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.04); catalogued as rs1272846335, COSV101223429; called by muse, mutect2, varscan2
- RTKN2 | c.1055A>G p.K352R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as COSV100189509; called by muse, mutect2, varscan2
- RUNX1T1 | c.94A>T p.T32S (on ENST00000265814 / NM_001198628.1; = p.T5S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99753408; called by muse, mutect2, varscan2
- RUNX3 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 95/340 reads (28%) | catalogued as COSV100136986; called by muse, mutect2, varscan2
- SAMSN1 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99581954; called by muse, mutect2, varscan2
- SEC61A1 | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 39/114 reads (34%) | catalogued as COSV99684932; called by muse, mutect2, varscan2
- SERBP1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 129/439 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100769140, COSV63413019; called by muse, mutect2, varscan2
- SERPINA3 | c.183C>A p.Y61* | Nonsense Mutation (SNP) | VAF 82/214 reads (38%) | catalogued as COSV101261756; called by muse, mutect2, varscan2
- SERPINB2 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100208147, COSV100208563; called by muse, mutect2, varscan2
- SH3TC2 | c.236G>C p.W79S | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV100102075; called by muse, mutect2, varscan2
- SHANK2 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99575137; called by muse, mutect2, varscan2
- SHC3 | c.1329G>T p.E443D | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV65437106; called by muse, mutect2, varscan2
- SHPRH | c.3502A>T p.S1168C (on ENST00000275233 / NM_001042683.3; = p.S1177C on NM_173082.3) | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99262392; called by muse, mutect2, varscan2
- SI | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100016383, COSV52303350; called by muse, mutect2, varscan2
- SIDT1 | c.1396T>A p.Y466N | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99334336; called by muse, mutect2, varscan2
- SIRPB1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV99498487; called by muse, mutect2, varscan2
- SLC17A6 | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54137537, COSV99581936; called by muse, mutect2, varscan2
- SLC17A6 | c.1184T>G p.M395R | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99581937; called by muse, mutect2, varscan2
- SLC24A4 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100105635; called by muse, varscan2
- SLC24A4 | c.1610C>A p.P537Q | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100105638, COSV54113701; called by muse, varscan2
- SLC25A41 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100383111; called by muse, mutect2, varscan2
- SLC39A12 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs150700069, COSV101070093; called by muse, mutect2, varscan2
- SLC41A2 | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99316691; called by muse, mutect2, varscan2
- SLC5A10 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525317, COSV58763209; called by muse, mutect2, varscan2
- SLC6A20 | c.1718C>A p.A573E | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV100653839; called by muse, mutect2, varscan2
- SLITRK2 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100157982; called by muse, mutect2, varscan2
- SLITRK4 | c.1759C>A p.P587T | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as COSV100567428; called by mutect2, varscan2
- SMARCA4 | c.3583C>A p.Q1195K | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100758856; called by muse, mutect2, varscan2
- SMC1B | c.1984A>G p.K662E | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV100663376; called by muse, mutect2, varscan2
- SOGA3 | c.2139C>A p.N713K | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100846992, COSV64106737; called by muse, mutect2, varscan2
- SORCS1 | c.2583C>A p.N861K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.115); catalogued as rs764843779, COSV99548200; called by muse, mutect2, varscan2
- SORCS3 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63802669; called by muse, mutect2, varscan2
- SPATA31D1 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 30/195 reads (15%) | catalogued as COSV61194266, COSV61200258; called by muse, mutect2, varscan2
- SPEN | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1388396024, COSV101005450; called by muse, mutect2, varscan2
- SPRY3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100249430; called by muse, mutect2, varscan2
- SPTBN4 | c.1363-1G>T p.X455_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100151551; called by muse, mutect2
- STAG2 | c.3047G>A p.R1016K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1569520230, COSV54350181, COSV99494489; called by muse, mutect2, varscan2
- STARD4 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99685368; called by muse, mutect2, varscan2
- SUPT16H | c.1396-2A>C p.X466_splice | Splice Site (SNP) | VAF 42/209 reads (20%) | catalogued as COSV99360037; called by muse, mutect2, varscan2
- SYNE1 | c.16377A>T p.K5459N (on ENST00000367255 / NM_182961.4; = p.K5388N on NM_033071.3) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99572230; called by muse, mutect2, varscan2
- SYNE1 | c.8705C>G p.S2902W (on ENST00000367255 / NM_182961.4; = p.S2909W on NM_033071.3) | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs576979843, COSV99572232; called by muse, mutect2, varscan2
- TBPL1 | c.386+1G>A p.X129_splice | Splice Site (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99260260; called by muse, mutect2, varscan2
- TG | c.6874G>A p.V2292M | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.232); catalogued as rs114404536, COSV99602084; called by muse, mutect2, varscan2
- TICAM1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99941171; called by muse, mutect2, varscan2
- TMC3 | c.522T>A p.F174L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV100845952; called by muse, mutect2, varscan2
- TMEM165 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs756532869, COSV101189670; called by muse, varscan2
- TMEM165 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101189671; called by muse, varscan2
- TMEM176A | c.430T>A p.Y144N | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99133854; called by muse, mutect2, varscan2
- TMEM236 | c.747A>G p.I249M | Missense Mutation (SNP) | VAF 307/600 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs905439451; called by muse, mutect2, varscan2
- TNFRSF19 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as rs759200699, COSV50311753; called by muse, mutect2, varscan2
- TNRC6A | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV100170281; called by muse, mutect2, varscan2
- TRBJ2-1 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1554511344; called by muse, mutect2, varscan2
- TRPV5 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV99520755; called by muse, mutect2, varscan2
- TTN | c.18478C>A p.Q6160K (on ENST00000591111; = p.Q5233K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | PolyPhen benign (0.082); catalogued as COSV100610939, COSV59984671; called by muse, mutect2, varscan2
- UBE2O | c.3114G>C p.K1038N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100039459; called by muse, mutect2, varscan2
- UNC13C | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99520549; called by mutect2, varscan2
- USP29 | c.2062C>A p.H688N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99518345; called by muse, mutect2, varscan2
- VIM | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56404615, COSV99813226; called by muse, mutect2, varscan2
- WDCP | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99722164; called by muse, mutect2, varscan2
- XKR4 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.228); catalogued as COSV100533272; called by muse, mutect2, varscan2
- XYLT1 | c.2855T>C p.V952A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as COSV99762591; called by muse, mutect2, varscan2
- YTHDF2 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100863812; called by muse, mutect2, varscan2
- ZBED9 | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV101509334; called by muse, mutect2, varscan2
- ZC3H14 | c.934G>T p.G312* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99193147; called by muse, mutect2, varscan2
- ZDHHC16 | c.1019+1G>C p.X340_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100512989; called by muse, mutect2
- ZDHHC17 | c.794C>A p.A265E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100602189; called by muse, mutect2, varscan2
- ZFYVE28 | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.239); catalogued as rs1241048728, COSV99343272; called by muse, mutect2
- ZGRF1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.453); catalogued as COSV100005658; called by muse, mutect2, varscan2
- ZKSCAN8 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as COSV100362958; called by muse, mutect2, varscan2
- ZMYND15 | c.1212G>C p.W404C | Missense Mutation (SNP) | VAF 152/447 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52641077, COSV99351552; called by muse, mutect2, varscan2
- ZNF18 | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as rs1410978404, COSV100503146; called by muse, mutect2, varscan2
- ZNF224 | c.307del p.I103Sfs*9 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as COSV100425409; called by mutect2, pindel, varscan2
- ZNF423 | c.3452A>T p.H1151L (on ENST00000563137 / NM_001379286.1; = p.H1143L on NM_015069.4) | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99282753; called by muse, mutect2, varscan2
- ZNF460 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV64415344; called by muse, mutect2, varscan2
- ZNF484 | c.2046T>A p.H682Q | Missense Mutation (SNP) | VAF 169/276 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1352354034, COSV100214770; called by muse, mutect2, varscan2
- ZNF804A | c.3319G>T p.A1107S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs193000214, COSV100169023; called by muse, mutect2, varscan2
- ZNF804A | c.3422C>A p.T1141N | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs768687369, COSV100169024; called by muse, mutect2, varscan2
- ZNF835 | c.538T>A p.Y180N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV101606378; called by muse, varscan2
- ZNF99 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | catalogued as COSV101233894; called by muse, mutect2, varscan2
- CCDC181 | c.97del p.S33Vfs*5 | Frame Shift Del (DEL) | VAF 47/181 reads (26%) | called by mutect2, pindel, varscan2
- CHRM3 | c.92del p.P31Rfs*44 | Frame Shift Del (DEL) | VAF 56/233 reads (24%) | called by mutect2, pindel, varscan2
- COL11A1 | c.1524del p.I509Sfs*19 | Frame Shift Del (DEL) | VAF 52/168 reads (31%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- DBT | c.1175del p.T392Kfs*21 | Frame Shift Del (DEL) | VAF 69/467 reads (15%) | called by mutect2, pindel, varscan2
- FCGBP | c.11660C>A p.A3887D | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRG1 | c.672del p.V225* | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- GAD1 | c.895dup p.A299Gfs*8 | Frame Shift Ins (INS) | VAF 56/191 reads (29%) | called by mutect2, pindel, varscan2
- GFPT2 | c.1230dup p.P411Tfs*6 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- IGHV3-15 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IQCH | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MPP2 | c.569_570del p.R190Hfs*17 (on ENST00000461854 / NM_001278372.2; = p.R166Hfs*17 on NM_005374.5) | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by pindel, varscan2
- PEX13 | c.1185del p.D397Mfs*32 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.466del p.V156Wfs*2 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- PREX2 | c.4664del p.P1555Hfs*11 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- PRKN | c.274del p.A92Rfs*11 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel, varscan2
- RASGRF1 | c.2739del p.N914Tfs*15 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | called by mutect2, pindel, varscan2
- RFC4 | c.379del p.A127Lfs*3 | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | called by mutect2, varscan2
- RGS1 | c.290del p.N97Mfs*7 | Frame Shift Del (DEL) | VAF 105/377 reads (28%) | called by mutect2, pindel, varscan2
- TRAV8-4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBV6-1 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, varscan2
- UPF3B | c.450dup p.V151Sfs*6 | Frame Shift Ins (INS) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- WRN | c.2068del p.L690* | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- ZNF778 | c.1279G>T p.G427W | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM29 | c.75C>T p.P25= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as COSV100822132; called by muse, mutect2, varscan2
- ADAMTS5 | c.471G>T p.A157= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs768285645, COSV53177892, COSV99538014; called by muse, mutect2, varscan2
- AMPH | c.342G>C p.V114= | Silent (SNP) | VAF 156/390 reads (40%) | catalogued as COSV100342942; called by muse, mutect2, varscan2
- AP3B2 | c.1737G>T p.A579= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV55610735, COSV99916751; called by muse, mutect2, varscan2
- ATP10A | c.1947C>T p.G649= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs1275264633, COSV63523341; called by muse, mutect2, varscan2
- C14orf119 | c.249T>C p.S83= | Silent (SNP) | VAF 47/250 reads (19%) | catalogued as COSV99399948; called by muse, mutect2, varscan2
- C3 | c.3591C>T p.A1197= | Silent (SNP) | VAF 138/343 reads (40%) | catalogued as rs776726007, COSV55582310; called by muse, mutect2, varscan2
- CACNA2D1 | c.1833T>A p.P611= (on ENST00000356253 / NM_001366867.1; = p.P592= on NM_000722.4) | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV100666949; called by muse, mutect2, varscan2
- CACNA2D4 | c.939C>A p.T313= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99766069; called by muse, mutect2, varscan2
- CALCR | c.231T>C p.D77= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs139631014; called by muse, mutect2, varscan2
- CATSPERD | c.1602C>G p.T534= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV100486894; called by muse, mutect2, varscan2
- CNTN3 | c.2592C>G p.A864= | Silent (SNP) | VAF 50/234 reads (21%) | catalogued as COSV99725342; called by muse, mutect2, varscan2
- COL6A6 | c.1597C>A p.R533= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100650591, COSV62026840; called by muse, mutect2, varscan2
- COL8A1 | c.2130C>A p.P710= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs770660787, COSV99658098; called by muse, mutect2, varscan2
- CRYBG1 | c.4749G>A p.Q1583= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as rs577957311, COSV100954574; called by muse, mutect2, varscan2
- CUBN | c.7491G>T p.L2497= | Silent (SNP) | VAF 46/335 reads (14%) | catalogued as COSV100913099; called by muse, mutect2, varscan2
- CYLC1 | c.822G>A p.K274= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100255030, COSV61413473; called by muse, mutect2, varscan2
- CYP4F2 | c.543G>A p.L181= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as COSV99171105; called by muse, mutect2
- DAPK1 | c.2919G>T p.L973= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs570648177, COSV100802444; called by muse, mutect2, varscan2
- DCLK1 | c.199C>A p.R67= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV55193218, COSV99711320, COSV99712147; called by muse, mutect2, varscan2
- DDX60L | c.1854T>C p.N618= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99487967; called by muse, mutect2, varscan2
- DLGAP3 | c.1941C>G p.T647= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99332927; called by muse, mutect2, varscan2
- DMAP1 | c.1062G>A p.P354= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs761939880, COSV100261770; called by mutect2, varscan2
- DNAH5 | c.8394T>C p.S2798= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99451824; called by muse, mutect2, varscan2
- DPP10 | c.15C>A p.A5= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV101342329; called by muse, mutect2, varscan2
- DYNC1H1 | c.2553G>T p.L851= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100795127; called by muse, varscan2
- EIF2AK1 | c.1638G>T p.P546= | Silent (SNP) | VAF 69/202 reads (34%) | catalogued as COSV99552130; called by muse, mutect2, varscan2
- EIF3H | c.912C>G p.L304= | Silent (SNP) | VAF 62/483 reads (13%) | catalogued as rs1011614643, COSV99412098; called by muse, mutect2, varscan2
- ESS2 | c.433C>T p.L145= | Silent (SNP) | VAF 96/269 reads (36%) | catalogued as COSV99351062; called by muse, mutect2, varscan2
- FBXO7 | c.1071G>C p.A357= | Silent (SNP) | VAF 94/293 reads (32%) | catalogued as COSV99832806; called by muse, mutect2, varscan2
- FHL5 | c.429C>A p.I143= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV58735939, COSV58739068; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1581T>C p.C527= | Silent (SNP) | VAF 66/215 reads (31%) | catalogued as COSV100437292; called by muse, mutect2, varscan2
- FYB1 | c.1596G>A p.K532= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as rs1288931199, COSV100685890; called by muse, mutect2, varscan2
- GALNT12 | c.1473G>A p.T491= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs373044668; called by muse, mutect2, varscan2
- GREB1 | c.2520C>T p.S840= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV99303341; called by muse, mutect2, varscan2
- GYPA | c.252C>A p.A84= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as COSV99302327; called by muse, mutect2, varscan2
- H2AZ2 | c.171G>T p.A57= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV56061955, COSV99760575; called by muse, mutect2, varscan2
- HP | c.856C>A p.R286= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs758923371, COSV100577583, COSV63326271; called by muse, mutect2, varscan2
- HPSE2 | c.1689T>A p.L563= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100986025; called by muse, mutect2, varscan2
- IGHG1 | c.234C>A p.T78= | Silent (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- ITIH2 | c.1638G>A p.T546= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as rs150260189, COSV64432132; called by muse, mutect2, varscan2
- KIF5A | c.2625G>A p.L875= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99673274; called by muse, mutect2, varscan2
- KLHL32 | c.993C>A p.P331= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100987419; called by muse, mutect2, varscan2
- KRT2 | c.525G>A p.K175= | Silent (SNP) | VAF 67/239 reads (28%) | catalogued as COSV100548564; called by muse, mutect2, varscan2
- KSR2 | c.864G>A p.P288= | Silent (SNP) | VAF 81/570 reads (14%) | catalogued as rs771169274, COSV60393836; called by muse, mutect2, varscan2
- LAMC2 | c.201G>A p.K67= | Silent (SNP) | VAF 236/653 reads (36%) | catalogued as COSV99917673; called by muse, mutect2, varscan2
- LIFR | c.2370C>T p.D790= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV54684488, COSV99664856; called by muse, mutect2, varscan2
- LPCAT1 | c.1017G>T p.R339= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV52038094; called by muse, mutect2, varscan2
- LRRIQ4 | c.1140G>T p.G380= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as COSV100540309; called by muse, mutect2, varscan2
- MAFB | c.438G>T p.P146= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100965059; called by muse, mutect2, varscan2
- MRPL42 | c.195G>C p.V65= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV100696639; called by muse, mutect2, varscan2
- MYBBP1A | c.3882G>C p.A1294= | Silent (SNP) | VAF 100/524 reads (19%) | catalogued as COSV54595558, COSV99626525; called by muse, mutect2, varscan2
- NEIL3 | c.1788G>T p.G596= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV99220746; called by muse, mutect2, varscan2
- NGFR | c.942G>A p.L314= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99412970; called by muse, mutect2, varscan2
- NOTCH3 | c.1206C>T p.C402= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs775946966, COSV99658085; called by muse, mutect2, varscan2
- OR10C1 | c.615C>A p.A205= (on ENST00000622521; = p.A203= on NM_013941.3) | Silent (SNP) | VAF 132/388 reads (34%) | catalogued as rs761736223, COSV101010861; called by muse, mutect2, varscan2
- OR10H1 | c.495C>T p.H165= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as rs781409715, COSV100612434; called by muse, mutect2, varscan2
- OR2T3 | c.336G>T p.L112= | Silent (SNP) | VAF 60/171 reads (35%) | catalogued as COSV100613305; called by muse, mutect2, varscan2
- OR52W1 | c.414T>A p.P138= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV100258696; called by muse, mutect2, varscan2
- OTOGL | c.5106T>A p.I1702= (on ENST00000547103; = p.I1693= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100087545; called by muse, mutect2, varscan2
- PARP10 | c.1536G>T p.V512= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV100478159; called by muse, mutect2, varscan2
- PCDH17 | c.1737C>T p.N579= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV64972042; called by muse, mutect2, varscan2
- PCDHA2 | c.1296G>A p.S432= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs1554119795, COSV65366882; called by muse, mutect2, varscan2
- PCDHA7 | c.1407G>T p.P469= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs1203887296, COSV100971647, COSV65348254; called by muse, mutect2, varscan2
- PCDHB12 | c.1248G>A p.E416= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs782421722, COSV99507533; called by muse, mutect2, varscan2
- PDYN | c.582C>T p.D194= | Silent (SNP) | VAF 96/265 reads (36%) | catalogued as rs769461186, COSV54101175, COSV54103394; called by muse, mutect2, varscan2
- PIGQ | c.1554G>T p.P518= (on ENST00000026218 / NM_148920.3; = p.R539L on NM_004204.5) | Silent (SNP) | VAF 114/290 reads (39%) | catalogued as COSV50320585, COSV99216281; called by muse, mutect2, varscan2
- PITRM1 | c.2061A>T p.I687= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs1301084841, COSV99829267; called by muse, mutect2, varscan2
- PKHD1L1 | c.12459C>T p.Y4153= | Silent (SNP) | VAF 66/150 reads (44%) | catalogued as COSV101006579; called by muse, mutect2, varscan2
- PLEC | c.10041G>C p.L3347= (on ENST00000322810 / NM_201380.4; = p.L3237= on NM_000445.5) | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100516387; called by muse, mutect2
- PROX1 | c.858C>T p.A286= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV99799848; called by muse, mutect2, varscan2
- PUF60 | c.666A>C p.A222= (on ENST00000526683 / NM_001362896.2; = p.A205= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100253750; called by muse, mutect2
- RADX | c.153G>A p.E51= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV100998878; called by muse, mutect2, varscan2
- RPS6KA6 | c.1896G>A p.E632= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV99425099; called by muse, mutect2, varscan2
- SCN4A | c.384C>T p.L128= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1385830950, COSV101438569; called by muse, mutect2
- SCN4A | c.213C>A p.P71= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101438570; called by muse, mutect2
- SEL1L3 | c.2532C>T p.Y844= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV53540221; called by muse, mutect2, varscan2
- SIX5 | c.2118G>T p.L706= | Silent (SNP) | VAF 75/203 reads (37%) | catalogued as COSV99353452; called by muse, mutect2, varscan2
- SLC22A4 | c.208C>A p.R70= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99569473; called by muse, mutect2
- SLC22A6 | c.396C>T p.A132= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100842867; called by muse, mutect2, varscan2
- SLC6A5 | c.2178C>T p.V726= | Silent (SNP) | VAF 53/340 reads (16%) | catalogued as rs796073436, COSV100117031; called by muse, mutect2, varscan2
- SLCO1B1 | c.1744C>T p.L582= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs757557255, COSV57018723; called by muse, mutect2, varscan2
- SLCO4C1 | c.909C>A p.V303= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100195360; called by muse, mutect2, varscan2
- SOX6 | c.1293C>G p.P431= (on ENST00000528429 / NM_001145819.2; = p.P390= on NM_017508.3) | Silent (SNP) | VAF 174/511 reads (34%) | catalogued as COSV100322683, COSV57045264; called by muse, mutect2, varscan2
- SOX9 | c.1401C>A p.T467= | Silent (SNP) | VAF 30/176 reads (17%) | catalogued as rs1161082323, COSV99818589; called by muse, mutect2, varscan2
- SPTA1 | c.6996C>A p.G2332= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100935232, COSV63759772; called by muse, mutect2, varscan2
- SVIL | c.5490G>C p.A1830= (on ENST00000355867 / NM_021738.3; = p.A1404= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV100881424; called by muse, mutect2, varscan2
- SYT11 | c.1053G>A p.K351= | Silent (SNP) | VAF 97/768 reads (13%) | catalogued as COSV64174437; called by muse, mutect2, varscan2
- TAP2 | c.195G>C p.L65= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV100885284; called by muse, mutect2, varscan2
- TAS1R3 | c.555C>A p.R185= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV100229687, COSV59565020; called by muse, mutect2, varscan2
- THSD7B | c.3621C>T p.V1207= (on ENST00000272643; = p.V1205= on NM_001316349.2) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99754731; called by muse, mutect2, varscan2
- TIAM2 | c.5127C>G p.V1709= (on ENST00000529824; = p.V1680= on NM_012454.3) | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV99265753; called by muse, mutect2, varscan2
- TMEM132B | c.2472G>A p.Q824= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV100170352; called by muse, mutect2, varscan2
- TNIK | c.348G>C p.L116= | Silent (SNP) | VAF 191/407 reads (47%) | catalogued as COSV99458447; called by muse, mutect2, varscan2
- TRBV6-1 | c.42G>A p.L14= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, varscan2
- TRIB2 | c.708C>T p.D236= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs767201489, COSV50231475; called by muse, mutect2, varscan2
- TRIM71 | c.2517G>A p.G839= | Silent (SNP) | VAF 51/302 reads (17%) | catalogued as rs1273335758, COSV101070468; called by muse, mutect2, varscan2
- USPL1 | c.3153A>G p.L1051= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV99687459; called by muse, mutect2, varscan2
- VRK2 | c.90A>T p.V30= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100418134; called by muse, mutect2, varscan2
- ZNF410 | c.864G>A p.K288= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV100206519, COSV100206623; called by muse, varscan2
- ZNF831 | c.1335C>A p.P445= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100926131; called by muse, mutect2, varscan2
- AKT2 | c.-1C>A | 5'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100251755; called by muse, mutect2, varscan2
- DCHS2 | n.1140A>T | RNA (SNP) | VAF 62/184 reads (34%) | catalogued as COSV100252466; called by muse, mutect2, varscan2
- DPP6 | c.*283A>G | 3'UTR (SNP) | VAF 45/119 reads (38%) | catalogued as COSV100126796; called by muse, mutect2, varscan2
- GBA3 | c.59-8400A>T | Intron (SNP) | VAF 98/481 reads (20%) | called by muse, mutect2, varscan2
- HERC2P3 | n.391G>T | RNA (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- MAPK8 | c.688+402G>T | Intron (SNP) | VAF 82/197 reads (42%) | called by muse, mutect2, varscan2
- OR2U1P | n.49G>T | RNA (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- PAPPA | c.*1G>A | 3'UTR (SNP) | VAF 37/271 reads (14%) | catalogued as COSV100074735; called by muse, mutect2, varscan2
- SPATA8 | n.740A>G | RNA (SNP) | VAF 44/145 reads (30%) | catalogued as COSV100139048; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2825C>A | Intron (SNP) | VAF 48/106 reads (45%) | catalogued as COSV100314562; called by muse, mutect2, varscan2
- TMEM105 | n.729C>T | RNA (SNP) | VAF 28/174 reads (16%) | catalogued as COSV59655062; called by muse, mutect2, varscan2
- TTN | c.34264+5492C>A | Intron (SNP) | VAF 45/75 reads (60%) | catalogued as COSV100621149; called by muse, mutect2, varscan2
- XIRP2 | c.*1115G>T | 3'UTR (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54691465, COSV99745288; called by muse, mutect2, varscan2
